Somatic mutation profile of tumor specimen 1105266 (aliquot 7316UP-1640-1105266) from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen 1105266: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17aa4213-aed1-4179-9306-a05d5dce5032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105277 (Blood Derived Normal), aliquot 7316UP-1640-1105277; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b019bfc4-8960-4437-a8e5-d0926c06be3d

The open-access MAF lists 156 somatic variants for this specimen: 110 protein-altering or splice-affecting, 24 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 24, Frame Shift Del 20, Intron 8, Splice Site 7, Nonsense Mutation 7, 5'UTR 6, Splice Region 5, In Frame Del 4, RNA 4, Frame Shift Ins 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1358_1359del p.K453Rfs*15 | Frame Shift Del (DEL) | VAF 86/119 reads (72%) | catalogued as rs1351986946; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.2313del p.R772Efs*8 | Frame Shift Del (DEL) | VAF 124/311 reads (40%) | catalogued as COSV52226795; called by mutect2, pindel, varscan2
- ANXA13 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 62/144 reads (43%) | catalogued as COSV51625648; called by muse, mutect2, varscan2
- CNOT1 | c.2481G>T p.S827= | Splice Region (SNP) | VAF 27/114 reads (24%) | catalogued as COSV55315051, COSV99801060; called by muse, mutect2, varscan2
- EHD2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2
- EXOC3L2 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.546); catalogued as rs146408436, COSV99374660; called by muse, mutect2, varscan2
- GMDS | c.1005C>G p.D335E | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV101070491; called by muse, mutect2, varscan2
- HOXA10 | c.946_948del p.K316del | In Frame Del (DEL) | VAF 364/667 reads (55%) | catalogued as rs1264111265; called by mutect2, pindel, varscan2
- IFT172 | c.5093T>C p.I1698T | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs762114339, COSV99274945; called by muse, mutect2, varscan2
- IGKV1-8 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 112/614 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs759609764; called by muse, mutect2, varscan2
- ITGAV | c.2706+7G>A | Splice Region (SNP) | VAF 230/237 reads (97%) | catalogued as rs776851066, COSV53719519; called by muse, mutect2, varscan2
- LRRC6 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189293241, COSV51538239; called by muse, mutect2, varscan2
- MAP4K1 | c.2341-7del | Splice Region (DEL) | VAF 43/121 reads (36%) | catalogued as rs767461672, COSV101204269; called by mutect2, pindel, varscan2
- MRPS18B | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 114/227 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs116524936; called by muse, mutect2, varscan2
- MSLNL | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 166/268 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766186362; called by muse, mutect2, varscan2
- PRDM16 | c.2851T>A p.Y951N | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99578259; called by muse, mutect2, varscan2
- PRSS53 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs778137757, COSV99762745; called by muse, mutect2, varscan2
- RAD54L2 | c.1812C>G p.S604R | Missense Mutation (SNP) | VAF 135/143 reads (94%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV56582303; called by muse, mutect2, varscan2
- RANBP3 | c.1473G>A p.S491= (on ENST00000340578 / NM_007322.3; = p.S486= on NM_003624.3) | Splice Region (SNP) | VAF 57/189 reads (30%) | catalogued as rs1012413726, COSV50382238; called by muse, mutect2, varscan2
- RASAL3 | c.2972C>A p.T991K | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV54604678; called by muse, mutect2, varscan2
- RASEF | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 437/573 reads (76%) | catalogued as rs1444601094, COSV100907060; called by muse, mutect2, varscan2
- SUGP1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 192/410 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs747643478, COSV55920060, COSV99895724; called by muse, mutect2, varscan2
- SULT1A1 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 136/502 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs746968899; called by muse, mutect2, varscan2
- TNR | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 129/140 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs368661657, COSV54873347; called by muse, mutect2, varscan2
- TP53 | c.944_945insCC p.P316Lfs*30 | Frame Shift Ins (INS) | VAF 140/197 reads (71%) | catalogued as COSV53220710; called by mutect2, pindel, varscan2
- TUSC2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 57/61 reads (93%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1553717633; called by muse, mutect2, varscan2
- ZNF292 | c.7081C>T p.R2361C | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs376564177; called by muse, mutect2, varscan2
- ADAMTS18 | c.1841_1842del p.R614Tfs*4 | Frame Shift Del (DEL) | VAF 196/550 reads (36%) | called by pindel, varscan2
- ADAP1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 513/524 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AGO2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 85/214 reads (40%) | called by muse, mutect2, varscan2
- ANGPT2 | c.1032+2_1032+35del p.X344_splice | Splice Site (DEL) | VAF 38/42 reads (90%) | called by mutect2, pindel
- ANKRD36 | c.2887-1G>T p.X963_splice | Splice Site (SNP) | VAF 96/480 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.1731del p.F578Lfs*50 | Frame Shift Del (DEL) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- ASB2 | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 234/242 reads (97%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATPAF1 | c.589-3_589-2del p.X197_splice (on ENST00000574428; = p.X220_splice on NM_022745.4) | Splice Site (DEL) | VAF 53/144 reads (37%) | called by pindel, varscan2
- BIRC2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- C2orf73 | c.343_368del p.L115Kfs*33 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | called by mutect2, pindel
- CFAP46 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 213/226 reads (94%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL9A1 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 356/717 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CSF3R | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 365/381 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DHX9 | c.3346A>C p.K1116Q | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DLC1 | c.3992G>T p.G1331V (on ENST00000276297 / NM_001348081.2; = p.G894V on NM_006094.5) | Missense Mutation (SNP) | VAF 79/86 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMD | c.9500A>G p.N3167S | Missense Mutation (SNP) | VAF 307/648 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAH17 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.457); called by mutect2, varscan2
- EAPP | c.402_411del p.D135Cfs*42 | Frame Shift Del (DEL) | VAF 70/274 reads (26%) | called by mutect2, pindel, varscan2
- ENDOD1 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 94/295 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPEP | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERRFI1 | c.488_491del p.S163Wfs*11 | Frame Shift Del (DEL) | VAF 203/223 reads (91%) | called by mutect2, pindel, varscan2
- ETAA1 | c.1011_1014del p.N337Kfs*10 | Frame Shift Del (DEL) | VAF 17/170 reads (10%) | called by mutect2, pindel
- EVI2B | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FAM181B | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FER1L5 | c.5383_5385del p.K1795del (on ENST00000623019; = p.K1759del on NM_001293083.2) | In Frame Del (DEL) | VAF 79/186 reads (42%) | called by mutect2, pindel, varscan2
- GART | c.812-4G>C | Splice Region (SNP) | VAF 38/85 reads (45%) | called by mutect2, varscan2
- GAS6 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 395/403 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GBA | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GLIPR1L2 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 84/92 reads (91%) | called by muse, mutect2, varscan2
- GPAA1 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 157/461 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GRIA2 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 61/65 reads (94%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK4 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 296/305 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KDF1 | c.1135T>C p.S379P | Missense Mutation (SNP) | VAF 194/209 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LRRC45 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 129/444 reads (29%) | called by muse, mutect2, varscan2
- MBD5 | c.2419_2432del p.L807Tfs*19 | Frame Shift Del (DEL) | VAF 53/65 reads (82%) | called by mutect2, pindel, varscan2
- MS4A12 | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT tolerated (0.25); called by muse, mutect2, varscan2
- MXRA5 | c.1944C>A p.Y648* | Nonsense Mutation (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- NCAN | c.3300_3319del p.Y1100* | Frame Shift Del (DEL) | VAF 136/508 reads (27%) | called by mutect2, pindel, varscan2
- NECTIN2 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NFKBIE | c.484_485del p.L162Afs*47 (on ENST00000275015; = p.L23Afs*47 on NM_004556.3) | Frame Shift Del (DEL) | VAF 262/744 reads (35%) | called by pindel, varscan2
- OR5I1 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR8G2P | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PDE5A | c.2058dup p.D687* | Frame Shift Ins (INS) | VAF 39/122 reads (32%) | called by pindel, varscan2
- PEG3 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGRMC2 | c.81T>A p.S27R | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PHLDA1 | c.821_856del p.A274_R286delinsG | In Frame Del (DEL) | VAF 113/121 reads (93%) | called by mutect2, pindel
- PI4K2A | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 163/174 reads (94%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R1 | c.1132_1172del p.N378Lfs*3 (on ENST00000521381 / NM_181523.3; = p.N108Lfs*3 on NM_181504.4) | Frame Shift Del (DEL) | VAF 67/74 reads (91%) | called by mutect2, pindel
- PKHD1L1 | c.3740C>A p.P1247Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- POLR2B | c.1064A>C p.D355A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PPP2R3B | c.1155dup p.D386Rfs*65 | Frame Shift Ins (INS) | VAF 82/257 reads (32%) | called by mutect2, pindel, varscan2
- PRCC | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 196/676 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.3442A>T p.T1148S | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- PSIP1 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 151/161 reads (94%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- R3HDM1 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, varscan2
- RNF40 | c.1899G>C p.R633S | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPS6KA3 | c.2064C>A p.Y688* | Nonsense Mutation (SNP) | VAF 245/554 reads (44%) | called by muse, mutect2, varscan2
- SAGE1 | c.1753_1762del p.E585Kfs*29 | Frame Shift Del (DEL) | VAF 107/113 reads (95%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SMARCC1 | c.2646+1G>A p.X882_splice | Splice Site (SNP) | VAF 96/103 reads (93%) | called by muse, mutect2, varscan2
- SMTNL1 | c.719A>G p.E240G (on ENST00000399154; = p.E277G on NM_001105565.2) | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPIRE2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- STK24 | c.462_463del p.H154Qfs*4 | Frame Shift Del (DEL) | VAF 90/143 reads (63%) | called by pindel, varscan2
- STX3 | c.772_773del p.Q259Gfs*35 | Frame Shift Del (DEL) | VAF 67/188 reads (36%) | called by pindel, varscan2
- TBX21 | c.1296G>A p.W432* | Nonsense Mutation (SNP) | VAF 167/341 reads (49%) | called by muse, mutect2, varscan2
- TDRD15 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TERF2 | c.56del p.D19Afs*140 | Frame Shift Del (DEL) | VAF 102/259 reads (39%) | called by mutect2, pindel, varscan2
- TMC6 | c.1969T>A p.C657S | Missense Mutation (SNP) | VAF 31/1233 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- TMEM38B | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TMPRSS7 | c.1672C>T p.P558S (on ENST00000452346; = p.P432S on NM_001042575.2) | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TOP1 | c.475_477del p.K159del | In Frame Del (DEL) | VAF 12/46 reads (26%) | called by pindel, varscan2
- TRIM9 | c.1073T>G p.V358G | Missense Mutation (SNP) | VAF 100/107 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP21 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VAT1L | c.789_790del p.L265Sfs*43 | Frame Shift Del (DEL) | VAF 79/254 reads (31%) | called by mutect2, pindel, varscan2
- ZFAND3 | c.396del p.K132Nfs*75 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ZFP82 | c.760T>G p.Y254D | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 92/270 reads (34%) | called by muse, mutect2
- ZNF329 | c.272T>G p.F91C | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF483 | c.2134del p.I712Ffs*61 | Frame Shift Del (DEL) | VAF 61/283 reads (22%) | called by mutect2, pindel, varscan2
- ZNF821 | c.260_261del p.E87Vfs*25 (on ENST00000425432 / NM_001376297.1; = p.E45Vfs*25 on NM_017530.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/258 reads (13%) | called by pindel, varscan2
- ACACB | c.3522C>T p.H1174= | Silent (SNP) | VAF 57/64 reads (89%) | catalogued as rs1032042057, COSV58143745; called by muse, mutect2, varscan2
- ACOT7 | c.378G>A p.A126= (on ENST00000377855 / NM_181864.3; = p.A116= on NM_007274.4) | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as rs369231427; called by muse, mutect2, varscan2
- ACSM2B | c.1662C>A p.V554= | Silent (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- BIRC2 | c.1086T>C p.T362= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- CARD10 | c.873G>T p.T291= | Silent (SNP) | VAF 50/215 reads (23%) | called by muse, mutect2
- CORO7 | c.237A>G p.L79= | Silent (SNP) | VAF 45/194 reads (23%) | called by muse, mutect2, varscan2
- CYSRT1 | c.414C>G p.A138= (on ENST00000409414; = p.A98= on NM_199001.5) | Silent (SNP) | VAF 189/203 reads (93%) | called by muse, mutect2, varscan2
- DNAH17 | c.9747C>G p.V3249= | Silent (SNP) | VAF 100/897 reads (11%) | called by muse, mutect2, varscan2
- EFHC2 | c.477C>T p.V159= | Silent (SNP) | VAF 106/214 reads (50%) | called by muse, mutect2, varscan2
- FAT1 | c.3846C>A p.G1282= | Silent (SNP) | VAF 147/159 reads (92%) | called by muse, mutect2, varscan2
- GRIN3B | c.621G>C p.R207= | Silent (SNP) | VAF 107/113 reads (95%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1779G>C p.L593= (on ENST00000642864 / NM_001111125.3; = p.L388= on NM_015075.2) | Silent (SNP) | VAF 116/268 reads (43%) | called by muse, mutect2, varscan2
- KSR2 | c.1683G>T p.L561= | Silent (SNP) | VAF 47/52 reads (90%) | called by muse, mutect2, varscan2
- PCDH8 | c.291C>T p.G97= | Silent (SNP) | VAF 156/355 reads (44%) | catalogued as COSV100131369; called by muse, mutect2, varscan2
- PTK2B | c.1293T>G p.L431= | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- RIN1 | c.2148G>A p.E716= | Silent (SNP) | VAF 89/172 reads (52%) | called by muse, mutect2, varscan2
- SCRN1 | c.27T>C p.C9= | Silent (SNP) | VAF 200/301 reads (66%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1014C>T p.Y338= | Silent (SNP) | VAF 127/263 reads (48%) | catalogued as rs765936170; called by muse, mutect2, varscan2
- TMEM64 | c.288C>G p.G96= | Silent (SNP) | VAF 65/292 reads (22%) | catalogued as COSV69127712; called by muse, mutect2, varscan2
- USP35 | c.537C>G p.A179= | Silent (SNP) | VAF 223/363 reads (61%) | called by muse, mutect2, varscan2
- VXN | c.444C>T p.S148= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- WDFY4 | c.4272C>G p.L1424= | Silent (SNP) | VAF 104/110 reads (95%) | called by muse, mutect2, varscan2
- ZBP1 | c.453C>T p.H151= | Silent (SNP) | VAF 140/226 reads (62%) | called by muse, mutect2, varscan2
- ZMYM1 | c.210A>G p.S70= | Silent (SNP) | VAF 56/58 reads (97%) | called by muse, varscan2
- AC008758.3 | n.486_487del | RNA (DEL) | VAF 90/235 reads (38%) | called by pindel, varscan2
- AC106795.1 | n.964+50T>C | Intron (SNP) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- AC136777.1 | n.272T>A | RNA (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.-84-1140_-84-1138del | Intron (DEL) | VAF 19/113 reads (17%) | catalogued as rs1234266281; called by pindel, varscan2
- ANKRD30A | c.2156-3577G>A | Intron (SNP) | VAF 17/113 reads (15%) | catalogued as rs1276733733; called by mutect2, varscan2
- CAMTA1 | c.*34T>A | 3'UTR (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65214129 G>C | 3'Flank (SNP) | VAF 144/320 reads (45%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.-23dup | 5'UTR (INS) | VAF 30/82 reads (37%) | called by mutect2, pindel
- CCT3 | c.304+355G>A | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- CRYM-AS1 | n.494C>A | RNA (SNP) | VAF 49/221 reads (22%) | catalogued as rs369254164; called by muse, mutect2, varscan2
- DECR2 | c.-47C>G | 5'UTR (SNP) | VAF 35/139 reads (25%) | catalogued as rs906429270; called by muse, mutect2, varscan2
- DRD2 | c.-11C>G | 5'UTR (SNP) | VAF 99/256 reads (39%) | called by muse, mutect2, varscan2
- GZMK | c.-45_-30del | 5'UTR (DEL) | VAF 51/63 reads (81%) | called by mutect2, pindel, varscan2
- IGF2BP2 | c.240-18385C>T | Intron (SNP) | VAF 81/701 reads (12%) | catalogued as rs765894861; called by muse, mutect2, varscan2
- MRPL10 | c.52+38G>A | Intron (SNP) | VAF 97/244 reads (40%) | catalogued as rs1462377202; called by muse, mutect2, varscan2
- NCOA3 | c.-16C>G | 5'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- RFK | chr9:76398726 A>T | 5'Flank (SNP) | VAF 62/589 reads (11%) | called by muse, mutect2, varscan2
- RIN2 | c.112-25C>G | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- RTN1 | c.1766-23029C>A | Intron (SNP) | VAF 127/140 reads (91%) | catalogued as rs373783767; called by muse, mutect2, varscan2
- SHISA8 | chr22:41909796 C>A | 3'Flank (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2468C>T | RNA (SNP) | VAF 291/310 reads (94%) | called by muse, mutect2, varscan2
- ZNF207 | c.-132G>C | 5'UTR (SNP) | VAF 44/45 reads (98%) | called by muse, mutect2, varscan2
